Somatic mutation profile of tumor specimen MMRF_1270_1_BM_CD138pos (aliquot MMRF_1270_1_BM_CD138pos_T1_KAS5U_L01213) from MMRF case MMRF_1270, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.0 years (23,752 days).
Specimen MMRF_1270_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29a0fb0e-006c-4d19-a3d6-47f8bb9aff3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1270_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1270_1_PB_Whole_C2_KAS5U_L01224; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73879489-9673-4e05-94ac-a3a2d87e7efb

The open-access MAF lists 119 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 33, Silent 15, Intron 11, 5'UTR 5, RNA 5, Nonsense Mutation 4, 3'Flank 3, Splice Region 2, Frame Shift Del 2, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.11798G>A p.G3933E | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.964); catalogued as rs751501210; called by muse, mutect2, varscan2
- C11orf95 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.312); catalogued as rs1326657337; called by muse, mutect2, varscan2
- C4orf54 | c.3899A>G p.E1300G | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1031384508; called by muse, mutect2, varscan2
- CACNG8 | c.275G>C p.C92S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV54414124; called by muse, mutect2, varscan2
- COL14A1 | c.3877C>T p.R1293W | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1156568233, COSV52852153; called by muse, mutect2, varscan2
- DSCAML1 | c.4804C>T p.R1602* (on ENST00000321322; = p.R1542* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 46/94 reads (49%) | catalogued as COSV100355644; called by muse, mutect2, varscan2
- FRY | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV66580894; called by muse, mutect2, varscan2
- IGBP1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV60556960; called by muse, mutect2, varscan2
- IGKV4-1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs748402676; called by muse, varscan2
- IGKV4-1 | c.320A>T p.E107V | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770988906; called by muse, varscan2
- IGLV1-40 | c.168G>C p.W56C | Missense Mutation (SNP) | VAF 48/51 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs752483277; called by muse, mutect2, varscan2
- IGLV6-57 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 77/84 reads (92%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs190816426; called by muse, mutect2, varscan2
- KAZN | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as rs1390497815; called by muse, mutect2, varscan2
- KCNJ1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs1171427929; called by muse, mutect2, varscan2
- KIF7 | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs147040400; called by muse, varscan2
- NKX6-3 | c.769G>A p.V257M (on ENST00000518699 / NM_001364841.2; = p.V127M on NM_152568.3) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs749019233; called by muse, mutect2, varscan2
- NSMCE1 | c.138C>G p.R46= | Splice Region (SNP) | VAF 13/34 reads (38%) | catalogued as rs1050299673; called by muse, mutect2, varscan2
- PDZRN4 | c.898C>T p.R300C (on ENST00000402685 / NM_001164595.2; = p.R42C on NM_013377.4) | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs919511511, COSV54197322; called by muse, mutect2, varscan2
- PLA2R1 | c.2828G>A p.W943* | Nonsense Mutation (SNP) | VAF 55/133 reads (41%) | catalogued as rs867433591; called by muse, mutect2, varscan2
- PPP1R3A | c.2203A>G p.T735A | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99493582; called by muse, mutect2, varscan2
- PRDM8 | c.1948A>C p.K650Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60202934; called by muse, mutect2, varscan2
- RP1 | c.1539C>A p.N513K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs764801304; called by muse, mutect2, varscan2
- RXFP3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.474); catalogued as rs1442701882, COSV57505093; called by muse, mutect2, varscan2
- SLC33A1 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.332); catalogued as rs756790835; called by muse, mutect2, varscan2
- TPP2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV65752327; called by muse, mutect2, varscan2
- ADGRB3 | c.854T>G p.F285C | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMP2K | c.2036G>C p.G679A | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- BRWD3 | c.3629T>A p.V1210E | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C6orf132 | c.1382G>A p.W461* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- CACNA1F | c.2492A>C p.E831A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CTC1 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.06); called by muse, mutect2
- DLG4 | c.776A>G p.D259G (on ENST00000399506 / NM_001321075.3; = p.D302G on NM_001365.4) | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DLGAP2 | c.1039A>G p.N347D | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DROSHA | c.2366+7T>C | Splice Region (SNP) | VAF 58/132 reads (44%) | called by muse, varscan2
- IGLV7-43 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ITGAD | c.3103C>T p.Q1035* | Nonsense Mutation (SNP) | VAF 48/50 reads (96%) | called by muse, mutect2, varscan2
- ITIH6 | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.281); called by mutect2, varscan2
- KLHL13 | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LAMA2 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- METTL4 | c.851T>C p.I284T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MSI2 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- PTPRC | c.2141A>C p.D714A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RPE | c.226C>T p.P76S (on ENST00000359429 / NM_001318926.1; = p.P8S on NM_006916.2) | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBCK | c.1870A>G p.I624V (on ENST00000273980 / NM_001163436.4; = p.I561V on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TLL2 | c.2134del p.V712Wfs*103 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, varscan2
- ZNF227 | c.2393del p.K798Sfs*22 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- BHLHE41 | c.720C>T p.S240= | Silent (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- DYSF | c.4056C>A p.I1352= | Silent (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- GFY | c.585A>T p.A195= | Silent (SNP) | VAF 9/220 reads (4%) | called by muse, mutect2
- HK1 | c.309G>A p.Q103= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1186330784; called by muse, mutect2, varscan2
- IGLV5-45 | c.96T>G p.S32= | Silent (SNP) | VAF 90/96 reads (94%) | catalogued as rs1422616569; called by muse, mutect2, varscan2
- NACC1 | c.684G>A p.V228= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs924304937; called by muse, mutect2, varscan2
- OR1A2 | c.87G>A p.V29= | Silent (SNP) | VAF 68/134 reads (51%) | catalogued as COSV67936120; called by muse, varscan2
- PLIN5 | c.1014C>T p.D338= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs189668026; called by muse, mutect2, varscan2
- RTP5 | c.201T>C p.H67= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- SLC30A10 | c.1171C>T p.L391= | Silent (SNP) | VAF 46/48 reads (96%) | called by muse, mutect2, varscan2
- SOX6 | c.114C>A p.A38= | Silent (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- TBC1D32 | c.1248T>C p.T416= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- TCEAL4 | c.240A>C p.G80= | Silent (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- TIMM21 | c.240C>T p.S80= | Silent (SNP) | VAF 11/33 reads (33%) | called by mutect2, varscan2
- ZNF268 | c.2229G>A p.Q743= | Silent (SNP) | VAF 101/206 reads (49%) | called by muse, mutect2, varscan2
- ACP3 | c.*1741_*1754del | 3'UTR (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- ACSS3 | c.*1026C>A | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- ACTBL2 | c.*1460C>A | 3'UTR (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- ANKRD19P | chr9:92809744 G>T | 5'Flank (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*637G>A | 3'UTR (SNP) | VAF 10/67 reads (15%) | catalogued as rs767186590; called by muse, mutect2, varscan2
- C1RL | c.72-66C>G | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- C1orf94 | c.-62C>T | 5'UTR (SNP) | VAF 107/204 reads (52%) | called by muse, mutect2, varscan2
- CD19 | c.995+115C>T | Intron (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- CEP85L | c.*1708A>G | 3'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- CNNM1 | c.*442G>A | 3'UTR (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- COX20 | c.*1291A>T | 3'UTR (SNP) | VAF 21/45 reads (47%) | catalogued as rs1486455834; called by muse, mutect2, varscan2
- CSH1 | c.11-77C>T | Intron (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- CYLC2 | c.*255G>A | 3'UTR (SNP) | VAF 13/51 reads (25%) | catalogued as rs867866876; called by muse, mutect2, varscan2
- CYP2G2P | n.1202A>C | RNA (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- DENND11 | c.*12A>G | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- DLG3 | c.*2217C>A | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- DNAH10 | c.13307-505G>T | Intron (SNP) | VAF 73/168 reads (43%) | called by muse, mutect2
- DTNA | c.1662+4664G>C | Intron (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- EBAG9 | c.*1427C>T | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- EBF2 | c.*773C>T | 3'UTR (SNP) | VAF 44/88 reads (50%) | catalogued as rs1021384276; called by muse, mutect2, varscan2
- EXOC1 | chr4:55905071 G>C | 3'Flank (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- FAM155A | c.*340A>T | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- FSTL4 | c.*1987C>A | 3'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- GABRA3 | c.*1067T>G | 3'UTR (SNP) | VAF 29/40 reads (73%) | called by muse, mutect2, varscan2
- GPATCH3 | c.*55T>A | 3'UTR (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- GPC4 | c.*756T>G | 3'UTR (SNP) | VAF 26/38 reads (68%) | called by muse, mutect2, varscan2
- HCN1 | c.-57G>T | 5'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2
- IFT81 | c.1645-154A>T | Intron (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- ITIH4 | c.*282G>C | 3'UTR (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- KIAA2012 | c.1832-128G>A | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- LINC02692 | n.182A>G | RNA (SNP) | VAF 42/78 reads (54%) | catalogued as rs1302673207; called by muse, mutect2
- LNPK | c.*5611_*5630del | 3'UTR (DEL) | VAF 16/54 reads (30%) | called by mutect2, varscan2
- LTB | c.163-20C>T | Intron (SNP) | VAF 107/243 reads (44%) | catalogued as rs536733696; called by muse, mutect2, varscan2
- MCTP1 | c.721-63998A>G | Intron (SNP) | VAF 29/59 reads (49%) | catalogued as rs767978995; called by muse, mutect2, varscan2
- MED12L | c.*673G>A | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- MMP16 | c.*3282T>G | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- NAA60 | c.*226_*232del | 3'UTR (DEL) | VAF 47/50 reads (94%) | called by mutect2, pindel, varscan2
- NEUROD4 | c.-3G>A | 5'UTR (SNP) | VAF 49/117 reads (42%) | catalogued as rs865841387, COSV99669892; called by muse, mutect2, varscan2
- PSG8 | chr19:42753370 G>T | 3'Flank (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- SCIN | c.*583T>C | 3'UTR (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- SLC46A3 | c.*1257C>T | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- SLC7A5P2 | n.22C>A | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as rs1567295185; called by muse, mutect2, varscan2
- SMARCD3 | c.1399-51G>A | Intron (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- SPANXN3 | c.-8C>A | 5'UTR (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2698A>T | RNA (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- TEAD1 | c.*6734T>A | 3'UTR (SNP) | VAF 24/39 reads (62%) | catalogued as rs1455575619; called by muse, varscan2
- TENM1 | c.*2019A>C | 3'UTR (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- TLL1 | c.-247C>T | 5'UTR (SNP) | VAF 77/142 reads (54%) | called by muse, mutect2, varscan2
- TLN1 | c.*365dup | 3'UTR (INS) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- TTC9 | c.*447G>A | 3'UTR (SNP) | VAF 83/181 reads (46%) | called by muse, mutect2, varscan2
- UBE3B | c.713+663C>G | Intron (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- UNC45B | c.*278A>G | 3'UTR (SNP) | VAF 60/100 reads (60%) | called by muse, mutect2, varscan2
- ZC3H6 | c.*7380G>C | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- ZIC1 | c.*993T>A | 3'UTR (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- ZNF148 | c.*5894T>C | 3'UTR (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- ZNF2 | chr2:95183189 G>T | 3'Flank (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- ZNF725P | n.296T>C | RNA (SNP) | VAF 30/178 reads (17%) | called by muse, mutect2, varscan2
- ZNF782 | c.*1076A>G | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
